Gene-level copy-number profile of tumor specimen TCGA-DX-A8BT-01A from TCGA case TCGA-DX-A8BT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 63.5 years (23,204 days).
Specimen TCGA-DX-A8BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d57d10f8-7e23-42fc-b5ab-144f14c87f87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd3d68b5-6f06-4d58-93af-2773542cabd8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 11,715; copy number 2: 37,256; copy number 3: 7,256; copy number 4: 3,326; copy number 5: 136; copy number 6: 8; copy number 7: 23; copy number 9: 3; copy number 10: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BT-01A-11D-A37B-01): tumor purity 0.64, ploidy 2.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,582,404–50,582,511, 1 gene: RNU6-1026P.
- chr4:189,764,391–190,092,279, 23 genes (within-gene range 0–1): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr18:3,894,699–4,024,150, 3 genes: RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr21:44,200,602–44,262,216, 6 genes: AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 233 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–5,781,696, 129 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:126,393,489–126,798,708, 5 genes, copy number 5: AL589787.2, LINC00601, C10orf90, AL589787.1, AL512272.1.
- chr10:126,988,095–127,026,507, 2 genes, copy number 5: AL359094.1, AL359094.2.
- chr14:26,599,755–27,295,516, 1 gene, copy number 9 (within-gene range 2–9): AL110292.1.
- chr14:26,873,092–28,490,362, 8 genes, copy number 6–9 (within-gene range 2–9): MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3.
- chr14:31,489,956–31,950,382, 7 genes, copy number 7 (within-gene range 2–7): NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313.
- chr14:32,879,246–36,679,362, 79 genes, copy number 6–10 (broad region; genes not listed).
- chr14:36,788,644–36,828,729, 2 genes, copy number 7 (within-gene range 2–7): AL162464.2, AL162464.1.

Autosomal genes at a single copy (total copy number 1): 10,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
